Somatic mutation profile of cancer-model specimen HCM-BROD-0953-C34-85B (Adherent Cell Line, passage 9; aliquot HCM-BROD-0953-C34-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-0953-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: GX; Age at diagnosis: 61.4 years (22,416 days).
Specimen HCM-BROD-0953-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18cdabe7-9358-49a3-be0d-c2bf86db4758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0953-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0953-C34-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f41204f2-30b9-46cd-9556-611833b5cdf4

The open-access MAF lists 583 somatic variants for this specimen: 441 protein-altering or splice-affecting, 124 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 383, Silent 124, Nonsense Mutation 28, Frame Shift Del 18, Intron 7, Splice Site 4, 3'Flank 3, Splice Region 3, RNA 3, 3'UTR 3, Nonstop Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 165/165 reads (100%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP164 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 172/799 reads (22%) | catalogued as rs780849567; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 159/484 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KERA | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 464/542 reads (86%) | catalogued as rs386833986, CM053937, COSV99899417; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 355/547 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as rs755542764; called by muse, mutect2, varscan2
- ABCD2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 420/2034 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV58051935; called by muse, mutect2, varscan2
- ADORA3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 150/358 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs764124230, COSV53986994; called by muse, mutect2, varscan2
- AHNAK | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 453/454 reads (100%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV57234612; called by muse, mutect2, varscan2
- ALOX12B | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 345/547 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59876387; called by muse, mutect2, varscan2
- AMER3 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 352/708 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100366495; called by muse, mutect2, varscan2
- ANKRD30B | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV57702586; called by muse, mutect2, varscan2
- APOB | c.7346G>A p.R2449K | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs576639442; called by muse, mutect2, varscan2
- ASXL2 | c.3980A>G p.Y1327C | Missense Mutation (SNP) | VAF 280/443 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413693845, COSV55470134; called by muse, mutect2, varscan2
- ASXL3 | c.5147T>C p.M1716T | Missense Mutation (SNP) | VAF 384/384 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs1228209823; called by muse, mutect2, varscan2
- ATP6V0D2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 63/630 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as rs773606779, COSV53417570; called by muse, mutect2
- BEND5 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 469/678 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs748499198, COSV65717838; called by muse, mutect2, varscan2
- BMPR1B | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs746760963; called by muse, mutect2, varscan2
- CACNB2 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 231/768 reads (30%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as rs750972281; called by muse, mutect2, varscan2
- CCDC3 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 278/939 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV66560793; called by muse, mutect2, varscan2
- CDH18 | c.992T>C p.L331S | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750805647, COSV56929778; called by muse, mutect2, varscan2
- CEACAM18 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67283098; called by muse, varscan2
- CFAP47 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 214/434 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs745711104; called by muse, mutect2, varscan2
- CHD2 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59119955; called by muse, mutect2, varscan2
- CLASP1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 253/558 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55323939; called by muse, mutect2, varscan2
- CLDN16 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 321/755 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1273948471; called by muse, mutect2, varscan2
- COL1A1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 152/619 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs770277944, CX137836; called by muse, mutect2, varscan2
- COL1A2 | c.3466A>G p.R1156G | Missense Mutation (SNP) | VAF 242/550 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV51967404; called by muse, mutect2, varscan2
- COL3A1 | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV58595952; called by muse, mutect2, varscan2
- CYP2E1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 139/437 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312885; called by muse, mutect2, varscan2
- DCHS2 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV100251688; called by muse, mutect2
- DDN | c.1368C>A p.D456E | Missense Mutation (SNP) | VAF 138/696 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100304897; called by muse, varscan2
- DDN | c.1247T>G p.L416R | Missense Mutation (SNP) | VAF 166/721 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.7); catalogued as rs370273938; called by muse, varscan2
- DPP6 | c.2519T>A p.I840N (on ENST00000377770 / NM_001364500.2; = p.I778N on NM_001936.5) | Missense Mutation (SNP) | VAF 377/700 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs767079091; called by muse, mutect2, varscan2
- DYSF | c.3152G>T p.S1051I | Missense Mutation (SNP) | VAF 191/560 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV50266304; called by muse, mutect2, varscan2
- EIF3L | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV67740135; called by muse, mutect2, varscan2
- EMSY | c.3244G>T p.A1082S | Missense Mutation (SNP) | VAF 367/469 reads (78%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.022); catalogued as COSV58260340; called by muse, mutect2, varscan2
- ENPP3 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as COSV62954575; called by muse, mutect2, varscan2
- ERC2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55609567; called by muse, mutect2, varscan2
- F8 | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950397, CM952096; called by muse, mutect2, varscan2
- FAM124B | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 267/697 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV66273168; called by muse, mutect2, varscan2
- FAM135B | c.3901G>T p.G1301W | Missense Mutation (SNP) | VAF 413/597 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99420222, COSV99428007; called by muse, mutect2, varscan2
- FAM221A | c.177del p.S60Hfs*44 | Frame Shift Del (DEL) | VAF 112/430 reads (26%) | catalogued as COSV61387686; called by mutect2, pindel, varscan2
- FAT1 | c.8113G>T p.E2705* | Nonsense Mutation (SNP) | VAF 46/377 reads (12%) | catalogued as COSV71676746; called by muse, mutect2, varscan2
- FLG | c.7799G>A p.R2600K | Missense Mutation (SNP) | VAF 157/715 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as COSV100912246, COSV64245155; called by muse, mutect2, varscan2
- FSIP2 | c.1796T>C p.I599T | Missense Mutation (SNP) | VAF 293/523 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1334348595; called by muse, mutect2, varscan2
- GBA3 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 248/252 reads (98%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV72438423; called by muse, mutect2
- GPR68 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 613/1245 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs969683832, COSV53176215; called by muse, mutect2, varscan2
- GRAMD1B | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 100/514 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV59203057; called by muse, mutect2, varscan2
- GRAMD1C | c.1189A>T p.T397S | Missense Mutation (SNP) | VAF 226/489 reads (46%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.985); catalogued as COSV100822842; called by muse, mutect2, varscan2
- GRID1 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 166/658 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191266908, COSV60050290; called by muse, mutect2, varscan2
- GRIN2B | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 245/477 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150445188; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GSE1 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 470/1108 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs771071094; called by muse, varscan2
- GUCY1B1 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.151); catalogued as COSV52378670; called by muse, mutect2
- HEPHL1 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59889178; called by muse, mutect2, varscan2
- HHIPL2 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 160/570 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563448, COSV99072536; called by muse, mutect2, varscan2
- IGF2BP1 | c.1376C>A p.P459Q | Missense Mutation (SNP) | VAF 304/417 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV99288337; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as rs1418997186; called by muse, mutect2, varscan2
- ITGA9 | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 301/301 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292500; called by muse, mutect2, varscan2
- ITSN2 | c.3259A>G p.T1087A | Missense Mutation (SNP) | VAF 168/241 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376221823; called by muse, mutect2, varscan2
- JCAD | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 178/669 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773935496, COSV64760302; called by muse, varscan2
- KCNA5 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 40/640 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); catalogued as rs886049575; ClinVar: uncertain significance; called by muse, mutect2
- KCNU1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101299440, COSV67760616; called by muse, mutect2, varscan2
- KEAP1 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 280/280 reads (100%) | catalogued as COSV50300677; called by muse, mutect2, varscan2
- KIF19 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 308/425 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV63430966; called by muse, varscan2
- KLC1 | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 503/967 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV55812394; called by muse, mutect2, varscan2
- KRTAP3-2 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 547/790 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1156352757; called by muse, mutect2, varscan2
- LAMA5 | c.6064C>T p.R2022W | Missense Mutation (SNP) | VAF 365/566 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs753064723; called by muse, mutect2, varscan2
- LRP1B | c.6280G>T p.A2094S | Missense Mutation (SNP) | VAF 290/516 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1194864758; called by muse, mutect2, varscan2
- LTBP1 | c.3890G>T p.C1297F (on ENST00000404816 / NM_206943.4; = p.C971F on NM_000627.4) | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395912779; called by muse, mutect2, varscan2
- MARK1 | c.101C>G p.S34W | Missense Mutation (SNP) | VAF 304/470 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs376677478, COSV99081356; called by muse, mutect2, varscan2
- MATN4 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 598/599 reads (100%) | PolyPhen benign (0.026); catalogued as rs1306835196, COSV59214063; called by muse, mutect2, varscan2
- MATR3 | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1274400535; called by muse, mutect2, varscan2
- MITD1 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 299/611 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56807002; called by muse, mutect2, varscan2
- MMP16 | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 244/797 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV54153098; called by muse, mutect2, varscan2
- MRGPRF | c.542_544del p.F181del | In Frame Del (DEL) | VAF 175/701 reads (25%) | catalogued as rs1367033473; called by mutect2, pindel, varscan2
- MUC3A | c.8339C>T p.A2780V | Missense Mutation (SNP) | VAF 200/948 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.053); catalogued as rs1358540202; called by muse, mutect2
- MYH13 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 52/596 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs1356172170, COSV52828446; called by muse, mutect2
- MYH13 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 254/739 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV52829974; called by muse, mutect2, varscan2
- MYO7B | c.2633G>T p.R878M | Missense Mutation (SNP) | VAF 268/677 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1375052999; called by muse, mutect2, varscan2
- NDUFS1 | c.1553+1G>A p.X518_splice | Splice Site (SNP) | VAF 88/181 reads (49%) | catalogued as rs1368324495, COSV51907925; called by muse, mutect2, varscan2
- NPAP1 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 205/464 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV61508819; called by muse, mutect2, varscan2
- NRXN1 | c.4377C>A p.S1459R | Missense Mutation (SNP) | VAF 270/434 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs758126649; called by mutect2, varscan2
- OR2F2 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 312/768 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68833451; called by muse, varscan2
- OR2G2 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 472/705 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.689); catalogued as COSV60742495; called by muse, varscan2
- OR2T11 | c.165del p.M56Cfs*47 | Frame Shift Del (DEL) | VAF 180/751 reads (24%) | catalogued as COSV100424837, COSV100424850; called by mutect2, pindel, varscan2
- OR51L1 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT tolerated (0.73); PolyPhen benign (0.054); catalogued as COSV58625969; called by muse, mutect2, varscan2
- OR5D13 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 364/364 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62333828; called by muse, varscan2
- OR5J2 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 346/347 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99044221; called by muse, mutect2, varscan2
- OR5T3 | c.615C>A p.H205Q | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs757557883; called by muse, mutect2, varscan2
- OR5T3 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV57380938, COSV57382707, COSV57383013; called by muse, mutect2, varscan2
- OTX1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 304/829 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375359674; called by muse, mutect2, varscan2
- PCCB | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 216/469 reads (46%) | catalogued as CM119113, COSV99291091; called by muse, mutect2, varscan2
- PCDHGA3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 282/544 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV99533838, COSV99548014; called by muse, mutect2, varscan2
- PCDHGB2 | c.957C>G p.I319M | Missense Mutation (SNP) | VAF 314/315 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs377144808, COSV53899179; called by muse, mutect2, varscan2
- PCDHGB2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 314/315 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1160500738; called by muse, mutect2, varscan2
- PCNX2 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 212/806 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV50848177; called by muse, mutect2, varscan2
- PDGFRA | c.2941C>A p.R981S | Missense Mutation (SNP) | VAF 322/414 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV57268573; called by muse, varscan2
- PDZRN4 | c.2097C>G p.I699M (on ENST00000402685 / NM_001164595.2; = p.I441M on NM_013377.4) | Missense Mutation (SNP) | VAF 191/991 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as COSV54219927; called by muse, mutect2, varscan2
- PEAK3 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 253/538 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1389918895; called by muse, mutect2, varscan2
- PGGT1B | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs755263515; called by muse, mutect2, varscan2
- PHEX | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101039496; called by muse, mutect2, varscan2
- PIK3C2G | c.681A>G p.S227= | Splice Region (SNP) | VAF 127/127 reads (100%) | catalogued as COSV56800988; called by muse, varscan2
- PNMA6A | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 472/940 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as rs1297904816; called by muse, varscan2
- PRCP | c.309G>A p.T103= | Splice Region (SNP) | VAF 36/49 reads (73%) | catalogued as rs773901335, COSV100476205, COSV57291140; called by muse, mutect2, varscan2
- PRDM9 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 119/697 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57007908; called by muse, mutect2, varscan2
- PTGFR | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.812); catalogued as rs1450094576; called by muse, mutect2, varscan2
- PTPRO | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 295/295 reads (100%) | catalogued as COSV55521537; called by muse, mutect2, varscan2
- PYHIN1 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 128/169 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs369613115; called by muse, mutect2, varscan2
- RAB6D | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs759678097; called by muse, mutect2, varscan2
- RADIL | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 245/695 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1399452976; called by muse, mutect2, varscan2
- RASSF7 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 130/616 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs766906576, COSV60346761; called by muse, mutect2, varscan2
- REG3G | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 120/404 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99709249; called by muse, mutect2
- RFPL4A | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 244/499 reads (49%) | catalogued as rs1379292861; called by muse, varscan2
- RTP5 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 706/1285 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV58321659; called by muse, mutect2, varscan2
- SGIP1 | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 47/84 reads (56%) | catalogued as COSV52766473, COSV52770350; called by muse, mutect2, varscan2
- SIGLEC8 | c.468G>T p.R156S | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs759296142, COSV58473883; called by muse, mutect2, varscan2
- SLC12A1 | c.2623A>T p.K875* | Nonsense Mutation (SNP) | VAF 85/189 reads (45%) | catalogued as COSV66797187; called by muse, mutect2, varscan2
- SLC13A4 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 165/310 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62460124; called by muse, mutect2, varscan2
- SLC27A6 | c.421T>A p.S141T | Missense Mutation (SNP) | VAF 387/388 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV52488865; called by muse, mutect2, varscan2
- SLC2A3 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 486/496 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50002058; called by muse, mutect2, varscan2
- SLC5A7 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 334/687 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983098939; called by muse, mutect2, varscan2
- SLC7A5 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 280/1008 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs771935980; called by muse, varscan2
- SSH2 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 346/460 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184610184; called by muse, mutect2, varscan2
- STK11 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 554/554 reads (100%) | catalogued as CM981865, COSV58820140; called by muse, varscan2
- SYT16 | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 361/747 reads (48%) | catalogued as COSV70857906, COSV70859771; called by muse, mutect2, varscan2
- TLL1 | c.1590C>A p.S530R | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs770750840, COSV50266616; called by muse, mutect2, varscan2
- TMEM131L | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 302/367 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1323356236; called by muse, mutect2, varscan2
- TNFAIP2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 416/931 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100281073; called by muse, mutect2, varscan2
- TPBGL | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 807/1009 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as rs1453718862; called by muse, mutect2, varscan2
- TRIM29 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 150/798 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs138412992; called by muse, varscan2
- TRPV5 | c.1578C>A p.Y526* | Nonsense Mutation (SNP) | VAF 30/872 reads (3%) | catalogued as COSV99520245; called by muse, mutect2
- TTC34 | c.2728G>T p.A910S | Missense Mutation (SNP) | VAF 266/610 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs564652956; called by muse, mutect2, varscan2
- TTC7A | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 215/636 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs760379792; called by muse, mutect2, varscan2
- TTN | c.97061C>A p.A32354D (on ENST00000591111; = p.A24930D on NM_003319.4) | Missense Mutation (SNP) | VAF 149/385 reads (39%) | PolyPhen probably damaging (0.966); catalogued as COSV100604531; called by muse, mutect2, varscan2
- TUBAL3 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 157/586 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554813896; called by muse, mutect2, varscan2
- TYR | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as rs76180653; called by muse, mutect2, varscan2
- UGT2A1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 374/478 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs1408467159; called by muse, mutect2
- USH2A | c.5065del p.E1689Nfs*25 | Frame Shift Del (DEL) | VAF 337/624 reads (54%) | catalogued as COSV100241255; called by mutect2, pindel, varscan2
- USP17L2 | c.553C>A p.H185N | Missense Mutation (SNP) | VAF 318/714 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1306460780; called by muse, mutect2, varscan2
- ZFHX4 | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 406/627 reads (65%) | SIFT tolerated (0.64); PolyPhen benign (0.085); catalogued as COSV99269099; called by muse, varscan2
- ZFHX4 | c.3167C>A p.T1056N | Missense Mutation (SNP) | VAF 245/1353 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV50792682; called by muse, mutect2, varscan2
- ZFP91 | c.1110G>T p.R370S | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100284304; called by muse, varscan2
- ZNF804A | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100168374; called by muse, mutect2, varscan2
- AAAS | c.1008G>T p.W336C | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AARS1 | c.549del p.C184Vfs*47 | Frame Shift Del (DEL) | VAF 86/622 reads (14%) | called by mutect2, pindel, varscan2
- AARS1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 221/808 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA12 | c.1766C>A p.P589H (on ENST00000272895 / NM_173076.3; = p.P271H on NM_015657.3) | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ABCC2 | c.2741G>A p.S914N | Missense Mutation (SNP) | VAF 134/496 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ABCG2 | c.1553A>T p.Y518F | Missense Mutation (SNP) | VAF 406/482 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ABCG8 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 335/550 reads (61%) | called by muse, mutect2, varscan2
- ABHD10 | c.223A>C p.S75R | Missense Mutation (SNP) | VAF 256/501 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ABHD16B | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 581/586 reads (99%) | called by muse, mutect2, varscan2
- ABHD17C | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTBL2 | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 356/550 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); called by muse, varscan2
- ADAD2 | c.1418C>T p.A473V (on ENST00000315906 / NM_001145400.2; = p.A555V on NM_139174.4) | Missense Mutation (SNP) | VAF 612/1087 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ADGRF4 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADGRL3 | c.2029T>A p.L677M (on ENST00000506720 / NM_001322402.2; = p.L609M on NM_015236.6) | Missense Mutation (SNP) | VAF 206/505 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AHNAK2 | c.7164G>T p.E2388D | Missense Mutation (SNP) | VAF 536/1087 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2
- AK5 | c.1043C>G p.S348C (on ENST00000354567 / NM_174858.3; = p.S322C on NM_012093.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAIN1 | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 344/344 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD55 | c.877_899del p.L293Afs*80 | Frame Shift Del (DEL) | VAF 562/1118 reads (50%) | called by pindel, varscan2
- APLP2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 79/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP39 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 54/1424 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- ARMC3 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 277/415 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAP2 | c.1028A>T p.N343I | Missense Mutation (SNP) | VAF 202/369 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB13 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 431/663 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATG4A | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 389/389 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP10A | c.3174G>T p.M1058I | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- BBS9 | c.2137G>T p.V713L (on ENST00000242067 / NM_001348036.1; = p.V673L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/397 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3032A>T p.D1011V | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BSDC1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C16orf78 | c.240del p.N81Tfs*12 | Frame Shift Del (DEL) | VAF 304/616 reads (49%) | called by mutect2, pindel, varscan2
- C4BPA | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 152/562 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- C4orf54 | c.4340C>A p.P1447H | Missense Mutation (SNP) | VAF 376/450 reads (84%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CA13 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 615/939 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CABP5 | c.344_345delinsT p.K115Mfs*54 | Frame Shift Del (DEL) | VAF 237/514 reads (46%) | called by pindel, varscan2*
- CACNA1H | c.2287G>C p.A763P | Missense Mutation (SNP) | VAF 707/708 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD36 | c.1221G>T p.R407S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH7 | c.2357A>T p.*786Lext*? (on ENST00000323011 / NM_033646.3; = p.*786Lext*21 on NM_004361.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 199/199 reads (100%) | called by muse, mutect2, varscan2
- CEACAM18 | c.594T>A p.Y198* | Nonsense Mutation (SNP) | VAF 531/531 reads (100%) | called by muse, mutect2, varscan2
- CEP164 | c.3015G>T p.Q1005H | Missense Mutation (SNP) | VAF 107/601 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CHRNA1 | c.1073G>T p.R358L (on ENST00000261007 / NM_001039523.3; = p.R333L on NM_000079.4) | Missense Mutation (SNP) | VAF 193/353 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CIT | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLPX | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by mutect2, varscan2
- CLRN3 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 171/578 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CNTNAP4 | c.2941G>T p.G981W | Missense Mutation (SNP) | VAF 214/531 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.3326C>A p.P1109H | Missense Mutation (SNP) | VAF 208/490 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- CPA2 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 240/432 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CPE | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CPS1 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by mutect2, varscan2
- CR1 | c.4934A>T p.H1645L | Missense Mutation (SNP) | VAF 287/415 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.158); called by muse, mutect2
- CREG2 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 354/771 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, varscan2
- CRYBA1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CRYBG3 | c.1013G>C p.W338S | Missense Mutation (SNP) | VAF 175/336 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.5027T>A p.L1676* (on ENST00000297405 / NM_001363185.1; = p.L1572* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 65/439 reads (15%) | called by muse, mutect2, varscan2
- CSRNP3 | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 220/401 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CXCL8 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 214/278 reads (77%) | SIFT tolerated (0.59); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CYP24A1 | c.531C>A p.N177K | Missense Mutation (SNP) | VAF 324/516 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP4Z1 | c.692A>T p.H231L | Missense Mutation (SNP) | VAF 174/426 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DLEC1 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 49/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.1871C>A p.P624H | Missense Mutation (SNP) | VAF 384/572 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DPYSL3 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 812/815 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAM | c.6015C>G p.Y2005* | Nonsense Mutation (SNP) | VAF 233/235 reads (99%) | called by muse, mutect2, varscan2
- DUSP13 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 189/663 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EBF4 | c.742C>A p.L248M (on ENST00000609451; = p.L244M on NM_001110514.1) | Missense Mutation (SNP) | VAF 433/434 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- EDARADD | c.243T>A p.D81E (on ENST00000334232 / NM_145861.4; = p.D71E on NM_080738.4) | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFR3B | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 551/928 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMC7 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 168/386 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- EML6 | c.4249A>T p.I1417F | Missense Mutation (SNP) | VAF 124/513 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- EPG5 | c.2138G>T p.G713V | Missense Mutation (SNP) | VAF 344/344 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.2294T>A p.L765* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- EPHA6 | c.1666T>A p.S556T | Missense Mutation (SNP) | VAF 350/647 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- EPHB6 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 224/648 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- EPPK1 | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 581/1779 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EVI5 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 153/266 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- EXOC6 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- EYS | c.4657A>T p.S1553C | Missense Mutation (SNP) | VAF 274/412 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EYS | c.4495G>T p.V1499L | Missense Mutation (SNP) | VAF 115/478 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAAP24 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 371/371 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FAM131C | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT3 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 310/401 reads (77%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.11678G>T p.G3893V | Missense Mutation (SNP) | VAF 388/454 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FBXL18 | c.896A>T p.K299M | Missense Mutation (SNP) | VAF 325/546 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- FBXL6 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 1576/2435 reads (65%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, varscan2
- FCRL5 | c.2477G>T p.G826V | Missense Mutation (SNP) | VAF 110/485 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FER | c.2422A>G p.S808G | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FEZF1 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 189/461 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- FEZF1 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 468/840 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FGF12 | c.178A>G p.R60G | Missense Mutation (SNP) | VAF 415/802 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by mutect2, varscan2
- FGFR2 | c.2300A>C p.E767A | Missense Mutation (SNP) | VAF 296/449 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMR1NB | c.229dup p.W77Lfs*33 | Frame Shift Ins (INS) | VAF 372/616 reads (60%) | called by pindel, varscan2
- FOXN4 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FREM1 | c.3387G>T p.K1129N | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FSIP2 | c.8935C>A p.Q2979K | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.10103C>A p.S3368Y | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA4 | c.1501G>C p.A501P | Missense Mutation (SNP) | VAF 388/468 reads (83%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, varscan2
- GABRA4 | c.806T>A p.M269K | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GALNTL6 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 431/521 reads (83%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAPVD1 | c.2092C>T p.L698F | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GCA | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 267/546 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.398); called by muse, varscan2
- GHR | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, varscan2
- GHR | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 87/88 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- GJA10 | c.278T>A p.M93K | Missense Mutation (SNP) | VAF 396/399 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- GJA10 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 430/430 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GLIPR1L1 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GOLGA2 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- GPR55 | c.19A>C p.S7R | Missense Mutation (SNP) | VAF 172/421 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR6 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 674/675 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM3 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 376/764 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2BC10 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 405/405 reads (100%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC10 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 427/427 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HELZ2 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 513/514 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, varscan2
- HNRNPA1P48 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 203/755 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 200/754 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- HS3ST3A1 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 350/1035 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HYDIN | c.2807A>G p.K936R | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IARS2 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- IFT140 | c.1988G>T p.C663F | Missense Mutation (SNP) | VAF 433/433 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGKV1-5 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 390/806 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGKV2-30 | c.355T>A p.W119R | Missense Mutation (SNP) | VAF 170/290 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV3-11 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 314/589 reads (53%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IL1RL1 | c.1622_1631del p.I541Rfs*5 | Frame Shift Del (DEL) | VAF 110/468 reads (24%) | called by mutect2, pindel
- IL20 | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 160/501 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INAFM2 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 77/602 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ITGA9 | c.1587G>T p.R529S | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMB3 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- KCTD8 | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 610/616 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KHDC1L | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 433/434 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1522 | c.769C>T p.P257S (on ENST00000373480 / NM_001198972.2; = p.P316S on NM_020888.3) | Missense Mutation (SNP) | VAF 270/623 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- KRT73 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 242/304 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KRT77 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 306/401 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- L1TD1 | c.515del p.G172Efs*10 | Frame Shift Del (DEL) | VAF 58/130 reads (45%) | called by mutect2, pindel, varscan2
- LCOR | c.1166G>T p.R389M | Missense Mutation (SNP) | VAF 354/547 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LEFTY2 | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 414/617 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- LGSN | c.1030T>A p.W344R | Missense Mutation (SNP) | VAF 481/674 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LINGO2 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- LPA | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LRFN5 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 310/714 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LRP1B | c.12686T>C p.L4229S | Missense Mutation (SNP) | VAF 149/396 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRRC7 | c.533T>A p.L178Q (on ENST00000651989 / NM_001370785.2; = p.L145Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/265 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LRRIQ1 | c.2079A>C p.E693D | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK1 | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LTN1 | c.4490C>G p.A1497G | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); called by muse, mutect2
- M1AP | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 353/574 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 246/515 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MAGEL2 | c.1209G>T p.W403C | Missense Mutation (SNP) | VAF 428/816 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MALL | c.224del p.L75Cfs*30 | Frame Shift Del (DEL) | VAF 185/787 reads (24%) | called by mutect2, pindel, varscan2
- MAP3K21 | c.2464G>T p.V822L | Missense Mutation (SNP) | VAF 157/630 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST4 | c.4684del p.E1562Kfs*42 (on ENST00000403625 / NM_001164664.2; = p.E1373Kfs*42 on NM_015183.3) | Frame Shift Del (DEL) | VAF 412/571 reads (72%) | called by mutect2, pindel, varscan2
- MEOX2 | c.711C>G p.N237K | Missense Mutation (SNP) | VAF 120/415 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MESP2 | c.932_933del p.S311Cfs*55 | Frame Shift Del (DEL) | VAF 140/352 reads (40%) | called by pindel, varscan2
- MMP12 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 99/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP16 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 572/884 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.383); called by muse, varscan2
- MON2 | c.4575G>T p.E1525D | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MROH1 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 481/1562 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.69C>G p.N23K | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MROH5 | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 266/845 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- MYO7A | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, varscan2
- NAP1L3 | c.1121T>A p.V374E | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- NAV2 | c.6478G>T p.G2160C (on ENST00000396087 / NM_001244963.2; = p.G2101C on NM_145117.5) | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBAS | c.1115G>T p.R372M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NCOA2 | c.4208G>T p.S1403I | Missense Mutation (SNP) | VAF 812/1221 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NDRG2 | c.278A>T p.Q93L (on ENST00000298687 / NM_001354570.1; = p.Q79L on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 277/668 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NEBL | c.2346G>A p.M782I | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NF1 | c.3961G>T p.V1321L | Missense Mutation (SNP) | VAF 109/159 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- NFASC | c.1483G>T p.D495Y (on ENST00000339876 / NM_001378329.1; = p.D506Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 580/807 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NGEF | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 310/571 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- NIPSNAP3B | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP4 | c.1404C>A p.S468R | Missense Mutation (SNP) | VAF 412/412 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.092); called by mutect2, varscan2
- NOS1 | c.2029T>A p.C677S | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- NPC1L1 | c.3893C>A p.P1298Q | Missense Mutation (SNP) | VAF 134/456 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPC1L1 | c.1449C>A p.Y483* | Nonsense Mutation (SNP) | VAF 332/477 reads (70%) | called by muse, mutect2, varscan2
- NPNT | c.552G>T p.R184S | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR2F1 | c.986C>G p.T329R | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NRROS | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 390/910 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- NT5DC1 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 402/402 reads (100%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, varscan2
- NTNG1 | c.1510G>C p.E504Q (on ENST00000370068 / NM_001113226.3; = p.E403Q on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 451/820 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NUP133 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NXNL1 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 363/364 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- OLFM3 | c.129+1G>A p.X43_splice | Splice Site (SNP) | VAF 113/230 reads (49%) | called by muse, mutect2, varscan2
- OLFML2A | c.1228A>G p.S410G | Missense Mutation (SNP) | VAF 37/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- OPLAH | c.3443del p.P1148Lfs*48 | Frame Shift Del (DEL) | VAF 504/1639 reads (31%) | called by mutect2, pindel, varscan2
- OR10G7 | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 133/940 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10J5 | c.746T>A p.V249D | Missense Mutation (SNP) | VAF 424/610 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- OR1P1 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 262/367 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by mutect2, varscan2
- OR51B6 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 382/383 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7G1 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OSBPL7 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PAPPA | c.3460C>A p.Q1154K | Missense Mutation (SNP) | VAF 474/475 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PARP1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 507/735 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PBX1 | c.1111-1G>T p.X371_splice | Splice Site (SNP) | VAF 150/507 reads (30%) | called by muse, mutect2, varscan2
- PBX1 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 150/510 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHGA12 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 534/535 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCLO | c.12683G>A p.G4228D | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PCLO | c.4463C>T p.P1488L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PER1 | c.2465G>C p.C822S | Missense Mutation (SNP) | VAF 397/630 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PIF1 | c.1458C>G p.N486K | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKHD1 | c.1759A>T p.S587C | Missense Mutation (SNP) | VAF 281/725 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, varscan2
- PKIA | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 161/673 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLB1 | c.3910A>G p.S1304G | Missense Mutation (SNP) | VAF 158/546 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- PML | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 255/511 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PMPCA | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PNCK | c.954G>T p.E318D (on ENST00000340888 / NM_001366975.1; = p.E401D on NM_001039582.3) | Missense Mutation (SNP) | VAF 494/494 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PNLIP | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 304/464 reads (66%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.1352G>T p.C451F | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POP1 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 155/1023 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POTEC | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 564/572 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by mutect2, varscan2
- PPARD | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 662/663 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM2 | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 183/423 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRKCH | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 62/970 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRR11 | c.1027A>G p.R343G | Missense Mutation (SNP) | VAF 97/452 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2B | c.2124G>C p.M708I | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- PTK2 | c.2692T>G p.Y898D | Missense Mutation (SNP) | VAF 145/924 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPN1 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 214/337 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PTPRB | c.4480G>T p.E1494* | Nonsense Mutation (SNP) | VAF 113/530 reads (21%) | called by muse, mutect2, varscan2
- PTPRH | c.2496C>A p.H832Q | Missense Mutation (SNP) | VAF 237/238 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PYHIN1 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.1452G>T p.L484F | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.462); called by mutect2, varscan2
- RBP3 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 267/963 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.6825C>A p.Y2275* | Nonsense Mutation (SNP) | VAF 372/680 reads (55%) | called by muse, varscan2
- RELN | c.6143G>C p.G2048A | Missense Mutation (SNP) | VAF 116/514 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- RFPL4AL1 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 237/508 reads (47%) | called by muse, mutect2, varscan2
- RFX6 | c.1259G>C p.S420T | Missense Mutation (SNP) | VAF 370/370 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- RIIAD1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 234/383 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPE65 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RSPO4 | c.406del p.Q136Rfs*90 | Frame Shift Del (DEL) | VAF 315/429 reads (73%) | called by mutect2, pindel, varscan2
- RUNDC3B | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.2051C>A p.P684H | Missense Mutation (SNP) | VAF 337/485 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- RYR2 | c.11091G>A p.K3697= | Splice Region (SNP) | VAF 125/175 reads (71%) | called by muse, mutect2, varscan2
- RYR2 | c.12207T>A p.C4069* | Nonsense Mutation (SNP) | VAF 392/568 reads (69%) | called by muse, mutect2, varscan2
- SAP25 | c.97G>T p.G33C (on ENST00000538735; = p.G131C on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 312/704 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SART1 | c.2221A>C p.M741L | Missense Mutation (SNP) | VAF 171/336 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.79); called by muse, varscan2
- SATL1 | c.627G>T p.M209I (on ENST00000395409; = p.M396I on NM_001012980.2) | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCAF11 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 353/429 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SEMA3C | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SET | c.262A>T p.I88F (on ENST00000372692 / NM_001374326.1; = p.I75F on NM_003011.4) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SH2B2 | c.1912C>A p.R638S | Missense Mutation (SNP) | VAF 370/754 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHISA6 | c.430A>G p.N144D | Missense Mutation (SNP) | VAF 76/968 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHISA6 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 194/630 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SI | c.4318G>T p.A1440S | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC13A1 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- SLC26A7 | c.1366G>T p.G456* | Nonsense Mutation (SNP) | VAF 220/865 reads (25%) | called by muse, mutect2, varscan2
- SLC35F2 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 334/423 reads (79%) | called by muse, mutect2, varscan2
- SLC5A9 | c.1031del p.P344Qfs*42 | Frame Shift Del (DEL) | VAF 198/798 reads (25%) | called by mutect2, pindel, varscan2
- SLC7A9 | c.1006C>G p.H336D | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SLCO1C1 | c.1631del p.D544Afs*13 | Frame Shift Del (DEL) | VAF 60/259 reads (23%) | called by mutect2, pindel, varscan2
- SMARCA5 | c.2444A>T p.E815V | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SMC1A | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SMYD1 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 130/392 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SON | c.5909G>A p.R1970H | Missense Mutation (SNP) | VAF 476/525 reads (91%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SORL1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 341/428 reads (80%) | called by muse, mutect2, varscan2
- SOS1 | c.1295G>T p.W432L | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SOX17 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 982/1493 reads (66%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SP1 | c.2081G>C p.R694P (on ENST00000327443 / NM_138473.3; = p.R687P on NM_003109.1) | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPDYE4 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 93/436 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SPESP1 | c.703T>G p.S235A | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPSB4 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 435/815 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SPTBN5 | c.5882G>T p.R1961L | Missense Mutation (SNP) | VAF 227/467 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- STRADA | c.315A>C p.E105D (on ENST00000336174 / NM_001363786.1; = p.E68D on NM_153335.6) | Missense Mutation (SNP) | VAF 217/323 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SULT6B1 | c.524G>A p.G175E (on ENST00000535679 / NM_001367551.1; = p.G137E on NM_001032377.2) | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TAF11L2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 501/502 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TCEAL5 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 435/437 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TECTA | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TEX47 | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TIGAR | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLCD5 | c.482A>T p.D161V (on ENST00000375095 / NM_001198671.2; = p.D183V on NM_001198670.2) | Missense Mutation (SNP) | VAF 416/538 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLR7 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM106B | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TMEM132B | c.1695C>A p.Y565* | Nonsense Mutation (SNP) | VAF 153/418 reads (37%) | called by muse, mutect2, varscan2
- TMEM178A | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 407/673 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TMEM237 | c.718G>T p.A240S (on ENST00000409883 / NM_001044385.3; = p.A232S on NM_152388.4) | Missense Mutation (SNP) | VAF 196/381 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM50A | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOR4A | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 807/807 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRPA1 | c.2570G>C p.G857A | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSNAX | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPAN10 | c.400G>T p.A134S (on ENST00000574882 / NM_001290212.1; = p.A96S on NM_031945.4) | Missense Mutation (SNP) | VAF 570/792 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- TTN | c.49282C>A p.P16428T (on ENST00000591111; = p.P9004T on NM_003319.4) | Missense Mutation (SNP) | VAF 159/432 reads (37%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBA4A | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 27/734 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TUBB8 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 91/394 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- UBE3B | c.3001G>C p.V1001L | Missense Mutation (SNP) | VAF 217/319 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- UGT1A4 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 343/778 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ULK1 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 264/423 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- UNC13D | c.374del p.G125Afs*20 | Frame Shift Del (DEL) | VAF 117/581 reads (20%) | called by mutect2, pindel, varscan2
- UNC80 | c.6243G>T p.K2081N | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- USH2A | c.1879C>A p.Q627K | Missense Mutation (SNP) | VAF 304/462 reads (66%) | SIFT tolerated (0.5); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UTP20 | c.7020del p.T2341Rfs*8 | Frame Shift Del (DEL) | VAF 104/1094 reads (10%) | called by mutect2, pindel, varscan2
- VRK1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 164/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSTM5 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- WDFY3 | c.1237G>C p.A413P | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- WFDC12 | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XIRP2 | c.1693C>A p.P565T (on ENST00000628543; = p.P740T on NM_152381.6) | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YWHAG | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 28/659 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBTB8B | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H11B | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 156/612 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZC3H7B | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 596/596 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.8570C>G p.T2857R | Missense Mutation (SNP) | VAF 224/1407 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF155 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF479 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF565 | c.941C>T p.T314I (on ENST00000355114; = p.T274I on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 502/503 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF831 | c.5033G>T p.*1678Lext*14 | Nonstop Mutation (SNP) | VAF 161/249 reads (65%) | called by muse, mutect2, varscan2
- ABL2 | c.2929C>A p.R977= (on ENST00000502732 / NM_007314.4; = p.R962= on NM_005158.5) | Silent (SNP) | VAF 201/652 reads (31%) | catalogued as COSV100773077, COSV61020833; called by muse, mutect2, varscan2
- ADARB2 | c.1455G>A p.V485= | Silent (SNP) | VAF 475/661 reads (72%) | catalogued as COSV67223663; called by muse, mutect2, varscan2
- ADAT3 | c.426G>T p.V142= | Silent (SNP) | VAF 112/877 reads (13%) | called by muse, mutect2, varscan2
- ADCK5 | c.273G>C p.L91= | Silent (SNP) | VAF 213/1081 reads (20%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4164C>A p.R1388= (on ENST00000506720 / NM_001322402.2; = p.R1277= on NM_015236.6) | Silent (SNP) | VAF 223/525 reads (42%) | called by muse, mutect2, varscan2
- AGO2 | c.711T>C p.V237= | Silent (SNP) | VAF 264/1065 reads (25%) | called by muse, mutect2, varscan2
- AIFM3 | c.348G>A p.L116= | Silent (SNP) | VAF 324/324 reads (100%) | called by muse, mutect2, varscan2
- ARMCX1 | c.435A>T p.P145= | Silent (SNP) | VAF 515/516 reads (100%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.258G>T p.R86= | Silent (SNP) | VAF 62/632 reads (10%) | called by muse, mutect2
- BRWD3 | c.1491G>T p.R497= | Silent (SNP) | VAF 136/136 reads (100%) | called by muse, mutect2, varscan2
- BTK | c.603A>C p.P201= | Silent (SNP) | VAF 35/317 reads (11%) | called by muse, mutect2, varscan2
- C1QA | c.120C>A p.G40= | Silent (SNP) | VAF 258/618 reads (42%) | catalogued as rs775331515; called by muse, mutect2, varscan2
- CARM1 | c.1761C>T p.G587= | Silent (SNP) | VAF 329/646 reads (51%) | catalogued as rs371408787; called by muse, mutect2, varscan2
- CBLIF | c.66C>G p.T22= | Silent (SNP) | VAF 256/256 reads (100%) | called by muse, mutect2, varscan2
- CCDC168 | c.3618A>G p.K1206= | Silent (SNP) | VAF 260/261 reads (100%) | called by muse, mutect2, varscan2
- CDH10 | c.919C>A p.R307= | Silent (SNP) | VAF 603/604 reads (100%) | catalogued as COSV100049639, COSV52591372; called by muse, mutect2, varscan2
- CFC1 | c.139C>A p.R47= | Silent (SNP) | VAF 326/1323 reads (25%) | called by muse, mutect2, varscan2
- CHRD | c.2562G>T p.S854= | Silent (SNP) | VAF 69/795 reads (9%) | called by muse, mutect2
- CHRM2 | c.552T>A p.A184= | Silent (SNP) | VAF 255/617 reads (41%) | called by muse, mutect2, varscan2
- CHST1 | c.687C>A p.V229= | Silent (SNP) | VAF 471/472 reads (100%) | called by muse, mutect2, varscan2
- CHST6 | c.96G>T p.S32= | Silent (SNP) | VAF 556/973 reads (57%) | catalogued as COSV100178521; called by muse, mutect2, varscan2
- CLMN | c.636G>T p.A212= | Silent (SNP) | VAF 319/668 reads (48%) | catalogued as COSV54183194; called by muse, mutect2, varscan2
- CLTC | c.4956G>A p.Q1652= | Silent (SNP) | VAF 259/362 reads (72%) | called by muse, mutect2, varscan2
- CNNM4 | c.1962A>T p.A654= | Silent (SNP) | VAF 246/530 reads (46%) | called by muse, mutect2, varscan2
- CPHXL | c.720C>T p.A240= | Silent (SNP) | VAF 300/837 reads (36%) | catalogued as rs956054089; called by muse, mutect2, varscan2
- DCDC1 | c.3696G>C p.V1232= (on ENST00000597505 / NM_001367979.1; = p.V339= on NM_020869.3) | Silent (SNP) | VAF 164/336 reads (49%) | called by muse, mutect2, varscan2
- DGKE | c.909A>T p.P303= | Silent (SNP) | VAF 253/335 reads (76%) | called by muse, mutect2, varscan2
- DOCK5 | c.4878C>T p.F1626= | Silent (SNP) | VAF 384/384 reads (100%) | called by muse, mutect2, varscan2
- DSE | c.2265G>T p.L755= | Silent (SNP) | VAF 405/405 reads (100%) | called by muse, mutect2, varscan2
- DZIP1 | c.1737A>T p.S579= (on ENST00000347108; = p.S560= on NM_014934.5) | Silent (SNP) | VAF 121/121 reads (100%) | called by muse, mutect2, varscan2
- EBF1 | c.187C>A p.R63= | Silent (SNP) | VAF 543/543 reads (100%) | catalogued as COSV58193946; called by muse, mutect2, varscan2
- EIF4B | c.1023T>G p.T341= | Silent (SNP) | VAF 296/360 reads (82%) | called by muse, mutect2, varscan2
- ERICH6B | c.1590G>T p.R530= | Silent (SNP) | VAF 172/172 reads (100%) | called by muse, mutect2, varscan2
- FAAP100 | c.894A>G p.A298= | Silent (SNP) | VAF 143/571 reads (25%) | called by muse, mutect2, varscan2
- FAM124B | c.1050G>T p.R350= | Silent (SNP) | VAF 265/699 reads (38%) | called by muse, mutect2, varscan2
- FAM171A2 | c.516C>G p.L172= | Silent (SNP) | VAF 471/664 reads (71%) | called by muse, mutect2, varscan2
- FAT3 | c.11901C>T p.I3967= | Silent (SNP) | VAF 94/442 reads (21%) | called by muse, mutect2, varscan2
- FGF12 | c.177G>A p.K59= | Silent (SNP) | VAF 448/867 reads (52%) | called by muse, mutect2, varscan2
- FGF20 | c.339G>T p.V113= | Silent (SNP) | VAF 276/276 reads (100%) | called by muse, mutect2, varscan2
- FHDC1 | c.378C>T p.H126= | Silent (SNP) | VAF 98/586 reads (17%) | called by muse, mutect2, varscan2
- FREM1 | c.3924G>A p.R1308= | Silent (SNP) | VAF 110/110 reads (100%) | catalogued as rs768902474, COSV101083620; called by muse, mutect2, varscan2
- FSBP | c.783G>A p.R261= | Silent (SNP) | VAF 456/686 reads (66%) | called by muse, mutect2, varscan2
- GJA10 | c.1251G>T p.G417= | Silent (SNP) | VAF 567/567 reads (100%) | catalogued as COSV65355245; called by muse, mutect2, varscan2
- GRHL3 | c.999G>A p.V333= (on ENST00000350501 / NM_198174.3; = p.V338= on NM_021180.3) | Silent (SNP) | VAF 177/352 reads (50%) | called by muse, varscan2
- GRK4 | c.327C>T p.F109= (on ENST00000398052 / NM_182982.3; = p.F77= on NM_005307.3) | Silent (SNP) | VAF 114/116 reads (98%) | catalogued as rs1338249695, COSV61667953; called by muse, mutect2
- GTPBP8 | c.258G>T p.T86= | Silent (SNP) | VAF 128/844 reads (15%) | called by muse, mutect2, varscan2
- HELLS | c.2094C>T p.P698= | Silent (SNP) | VAF 90/323 reads (28%) | catalogued as rs758021485; called by muse, mutect2, varscan2
- IFT172 | c.2454C>G p.L818= | Silent (SNP) | VAF 170/479 reads (35%) | called by muse, mutect2, varscan2
- IRF2 | c.30G>T p.P10= | Silent (SNP) | VAF 316/394 reads (80%) | called by muse, mutect2, varscan2
- JPH2 | c.408C>A p.G136= | Silent (SNP) | VAF 508/508 reads (100%) | called by muse, mutect2, varscan2
- KDM4C | c.2595G>A p.K865= | Silent (SNP) | VAF 213/213 reads (100%) | catalogued as rs1433092022; called by muse, mutect2, varscan2
- KERA | c.507C>G p.T169= | Silent (SNP) | VAF 65/634 reads (10%) | catalogued as COSV57131999; called by muse, mutect2, varscan2
- KMT2D | c.15420G>T p.G5140= | Silent (SNP) | VAF 165/756 reads (22%) | called by muse, mutect2, varscan2
- LAMB1 | c.3429G>A p.Q1143= | Silent (SNP) | VAF 283/501 reads (56%) | called by muse, mutect2, varscan2
- LAPTM5 | c.519C>T p.L173= | Silent (SNP) | VAF 142/268 reads (53%) | called by muse, mutect2, varscan2
- LMLN | c.1083A>T p.L361= | Silent (SNP) | VAF 153/363 reads (42%) | catalogued as COSV57599265; called by muse, mutect2, varscan2
- LRP1B | c.12939G>A p.P4313= | Silent (SNP) | VAF 266/470 reads (57%) | catalogued as rs369634559, COSV101260542; called by muse, mutect2, varscan2
- LRP1B | c.2214G>A p.L738= | Silent (SNP) | VAF 113/305 reads (37%) | called by muse, mutect2, varscan2
- MGA | c.8385A>T p.V2795= (on ENST00000219905 / NM_001164273.1; = p.V2586= on NM_001080541.2) | Silent (SNP) | VAF 13/259 reads (5%) | called by muse, mutect2
- MGAM | c.891T>G p.T297= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- MTRNR2L5 | c.57T>G p.P19= | Silent (SNP) | VAF 214/332 reads (64%) | called by muse, mutect2
- MUC12 | c.5310C>T p.S1770= (on ENST00000379442; = p.S1627= on NM_001164462.1) | Silent (SNP) | VAF 522/1087 reads (48%) | called by muse, mutect2, varscan2
- MUC16 | c.8595C>A p.A2865= | Silent (SNP) | VAF 268/269 reads (100%) | called by muse, mutect2, varscan2
- NAV3 | c.4359G>A p.Q1453= | Silent (SNP) | VAF 35/727 reads (5%) | catalogued as rs1349460724; called by muse, mutect2
- NEURL1B | c.726G>T p.A242= | Silent (SNP) | VAF 393/393 reads (100%) | catalogued as COSV63940244; called by muse, mutect2, varscan2
- NLRP3 | c.975G>C p.R325= | Silent (SNP) | VAF 205/765 reads (27%) | catalogued as COSV60219416, COSV60229185; called by muse, mutect2, varscan2
- NOX4 | c.1221G>A p.L407= | Silent (SNP) | VAF 165/206 reads (80%) | catalogued as rs536841215, COSV54463900; called by muse, varscan2
- NPAP1 | c.459C>A p.A153= | Silent (SNP) | VAF 165/367 reads (45%) | called by muse, mutect2, varscan2
- NRIP2 | c.24C>A p.S8= | Silent (SNP) | VAF 219/219 reads (100%) | called by muse, varscan2
- OR10J5 | c.714C>A p.A238= | Silent (SNP) | VAF 185/650 reads (28%) | catalogued as COSV58384817; called by muse, varscan2
- OR1F1 | c.615G>A p.L205= | Silent (SNP) | VAF 324/324 reads (100%) | called by muse, mutect2, varscan2
- OR2C3 | c.628C>T p.L210= | Silent (SNP) | VAF 427/614 reads (70%) | catalogued as rs764131898; called by muse, mutect2, varscan2
- OR2T10 | c.804T>G p.P268= | Silent (SNP) | VAF 242/354 reads (68%) | called by muse, mutect2, varscan2
- OR2W3 | c.78C>A p.I26= | Silent (SNP) | VAF 472/680 reads (69%) | called by muse, varscan2
- OR3A3 | c.727A>C p.R243= | Silent (SNP) | VAF 40/601 reads (7%) | called by muse, mutect2
- OR4K13 | c.415C>A p.R139= | Silent (SNP) | VAF 315/601 reads (52%) | called by muse, mutect2, varscan2
- OR8B8 | c.189C>G p.L63= | Silent (SNP) | VAF 104/535 reads (19%) | called by muse, mutect2, varscan2
- P2RX7 | c.558A>G p.E186= | Silent (SNP) | VAF 117/298 reads (39%) | called by muse, mutect2, varscan2
- PCCB | c.1287C>A p.V429= | Silent (SNP) | VAF 293/527 reads (56%) | called by muse, mutect2, varscan2
- PCDH15 | c.2895T>C p.Y965= | Silent (SNP) | VAF 114/152 reads (75%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.210G>A p.A70= | Silent (SNP) | VAF 36/712 reads (5%) | catalogued as rs749007839; called by muse, mutect2
- PGBD4 | c.777A>T p.P259= | Silent (SNP) | VAF 162/327 reads (50%) | called by muse, mutect2, varscan2
- PLXND1 | c.435G>A p.Q145= | Silent (SNP) | VAF 572/1201 reads (48%) | catalogued as rs1443692339; called by muse, mutect2, varscan2
- POLG | c.1398G>T p.L466= | Silent (SNP) | VAF 117/296 reads (40%) | called by muse, mutect2, varscan2
- PPP3R2 | c.24G>T p.P8= | Silent (SNP) | VAF 305/306 reads (100%) | catalogued as rs367897972; called by muse, mutect2, varscan2
- PRPSAP2 | c.651C>A p.A217= | Silent (SNP) | VAF 52/720 reads (7%) | catalogued as COSV99264725; called by muse, mutect2
- PSG5 | c.339C>A p.T113= | Silent (SNP) | VAF 322/322 reads (100%) | called by muse, mutect2, varscan2
- PTPN12 | c.1785C>G p.L595= | Silent (SNP) | VAF 69/355 reads (19%) | called by muse, mutect2, varscan2
- R3HDM2 | c.2424C>A p.S808= | Silent (SNP) | VAF 201/279 reads (72%) | called by muse, mutect2, varscan2
- RADIL | c.2979G>A p.G993= | Silent (SNP) | VAF 323/505 reads (64%) | catalogued as rs1210087477; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1260C>T p.F420= (on ENST00000408927 / NM_001100427.2; = p.F421= on NM_021159.5) | Silent (SNP) | VAF 51/64 reads (80%) | called by muse, mutect2, varscan2
- RASGEF1B | c.153C>A p.S51= | Silent (SNP) | VAF 256/329 reads (78%) | called by muse, mutect2, varscan2
- RYR2 | c.2052C>A p.P684= | Silent (SNP) | VAF 339/487 reads (70%) | catalogued as COSV63674224; called by muse, mutect2, varscan2
- SERPING1 | c.999C>A p.A333= | Silent (SNP) | VAF 79/338 reads (23%) | called by mutect2, varscan2
- SH2B2 | c.504G>A p.A168= | Silent (SNP) | VAF 565/1020 reads (55%) | called by muse, mutect2, varscan2
- SNRPN | c.618C>A p.P206= | Silent (SNP) | VAF 215/485 reads (44%) | called by muse, mutect2, varscan2
- SPDYE4 | c.351C>G p.V117= | Silent (SNP) | VAF 93/436 reads (21%) | catalogued as COSV60904986; called by muse, mutect2, varscan2
- SPTA1 | c.2812C>T p.L938= | Silent (SNP) | VAF 223/318 reads (70%) | called by muse, mutect2, varscan2
- SUCO | c.3360C>T p.T1120= | Silent (SNP) | VAF 117/433 reads (27%) | called by muse, mutect2, varscan2
- SYN3 | c.1455G>T p.P485= | Silent (SNP) | VAF 572/572 reads (100%) | called by muse, mutect2, varscan2
- TAF11L2 | c.369G>T p.A123= | Silent (SNP) | VAF 507/507 reads (100%) | called by muse, mutect2, varscan2
- TAS2R14 | c.444A>T p.I148= | Silent (SNP) | VAF 275/276 reads (100%) | called by muse, mutect2, varscan2
- TCHHL1 | c.12C>A p.L4= | Silent (SNP) | VAF 119/407 reads (29%) | catalogued as COSV64288088; called by muse, mutect2, varscan2
- TENM3 | c.3699A>T p.T1233= | Silent (SNP) | VAF 350/430 reads (81%) | called by muse, varscan2
- TEX47 | c.348C>G p.G116= | Silent (SNP) | VAF 81/212 reads (38%) | called by muse, mutect2, varscan2
- THSD7A | c.3372C>G p.T1124= | Silent (SNP) | VAF 179/432 reads (41%) | called by muse, mutect2, varscan2
- TIMD4 | c.744C>A p.V248= | Silent (SNP) | VAF 219/219 reads (100%) | called by muse, mutect2, varscan2
- TLR7 | c.891A>T p.L297= | Silent (SNP) | VAF 382/383 reads (100%) | called by muse, mutect2, varscan2
- TPO | c.1725G>A p.L575= | Silent (SNP) | VAF 168/828 reads (20%) | called by muse, mutect2, varscan2
- TRPM2 | c.2295G>T p.L765= | Silent (SNP) | VAF 248/751 reads (33%) | called by muse, mutect2, varscan2
- TRPM7 | c.5598A>G p.*1866= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as rs1409597249; called by muse, mutect2, varscan2
- TRPV4 | c.2397G>T p.P799= | Silent (SNP) | VAF 115/376 reads (31%) | catalogued as COSV55682740; called by muse, mutect2, varscan2
- TTC6 | c.321G>T p.A107= | Silent (SNP) | VAF 460/1053 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.97062C>A p.A32354= (on ENST00000591111; = p.A24930= on NM_003319.4) | Silent (SNP) | VAF 149/384 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.81987C>A p.G27329= (on ENST00000591111; = p.G19905= on NM_003319.4) | Silent (SNP) | VAF 308/749 reads (41%) | catalogued as COSV60179263; called by muse, mutect2, varscan2
- USH2A | c.6717C>T p.D2239= | Silent (SNP) | VAF 447/679 reads (66%) | catalogued as COSV56375246; called by muse, mutect2, varscan2
- USP37 | c.1140A>T p.P380= | Silent (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- USP53 | c.2397A>G p.L799= | Silent (SNP) | VAF 103/124 reads (83%) | catalogued as rs1344153282; called by muse, mutect2, varscan2
- WDR45B | c.300A>G p.T100= | Silent (SNP) | VAF 106/430 reads (25%) | called by muse, mutect2, varscan2
- ZC3H11B | c.1146A>T p.T382= | Silent (SNP) | VAF 14/20 reads (70%) | called by mutect2, varscan2
- ZFHX3 | c.1284C>T p.T428= | Silent (SNP) | VAF 461/672 reads (69%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4557G>T p.R1519= | Silent (SNP) | VAF 340/1104 reads (31%) | called by muse, mutect2, varscan2
- ZNF282 | c.1765C>T p.L589= | Silent (SNP) | VAF 273/766 reads (36%) | catalogued as rs139582643; called by muse, mutect2, varscan2
- ZNF526 | c.189C>T p.G63= | Silent (SNP) | VAF 228/481 reads (47%) | called by muse, mutect2, varscan2
- ASAH1 | c.505+57_505+59del | Intron (DEL) | VAF 289/294 reads (98%) | catalogued as rs1362075831; called by pindel, varscan2
- ATP6AP1L | n.1441G>A | RNA (SNP) | VAF 278/278 reads (100%) | called by muse, mutect2, varscan2
- CDHR1 | chr10:84219135 A>T | 3'Flank (SNP) | VAF 133/517 reads (26%) | called by muse, mutect2
- CTCFL | c.1059+108T>C | Intron (SNP) | VAF 80/206 reads (39%) | called by muse, mutect2, varscan2
- CYP4F8 | c.343+86T>A | Intron (SNP) | VAF 71/71 reads (100%) | called by muse, mutect2, varscan2
- DTNA | c.1094+1368G>A | Intron (SNP) | VAF 152/343 reads (44%) | catalogued as rs777774345; called by muse, mutect2, varscan2
- ETV1 | c.-88+103G>T | Intron (SNP) | VAF 270/425 reads (64%) | called by muse, mutect2, varscan2
- IGHA1 | chr14:105704517 G>T | 3'Flank (SNP) | VAF 287/785 reads (37%) | catalogued as rs1367129991; called by muse, mutect2, varscan2
- LRRC41 | chr1:46278005 C>T | 3'Flank (SNP) | VAF 252/954 reads (26%) | called by muse, mutect2, varscan2
- NUDCD1 | c.*947A>G | 3'UTR (SNP) | VAF 187/982 reads (19%) | called by muse, mutect2, varscan2
- NXF5 | n.1178G>T | RNA (SNP) | VAF 28/29 reads (97%) | called by mutect2, varscan2
- PCF11 | c.-141A>T | 5'UTR (SNP) | VAF 585/759 reads (77%) | called by muse, mutect2, varscan2
- REXO1L1P | n.706G>T | RNA (SNP) | VAF 255/2073 reads (12%) | catalogued as rs1382386980; called by muse, mutect2, varscan2
- RIMS2 | c.698+52990G>A | Intron (SNP) | VAF 26/464 reads (6%) | catalogued as rs377178152, COSV51684277; called by muse, mutect2
- RNMT | c.*2109A>T | 3'UTR (SNP) | VAF 366/367 reads (100%) | called by muse, mutect2, varscan2
- RPL23AP49 | chr3:75672409 A>G | 5'Flank (SNP) | VAF 92/316 reads (29%) | called by muse, mutect2, varscan2
- SGIP1 | c.99+1028T>A | Intron (SNP) | VAF 257/439 reads (59%) | called by muse, mutect2, varscan2
- SYNGR1 | c.*2614C>T | 3'UTR (SNP) | VAF 272/275 reads (99%) | catalogued as rs745337198; called by muse, mutect2, varscan2
